Surgical pathology report (de-identified scan), TCGA case TCGA-55-8097, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8097-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO: [REDACTED]

Pre-Op Diagnosis
Lung nodule
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Four parts

Container labeled "[REDACTED] - level 10 lymph node" has 2.0 x 1.0 x 0.4 cm of shaggy gray-pink to brown-black focally nodular-appearing, focally fleshy tissue fragments with staple lines in place. As much tissue as possible away from the staple line is submitted in a single cassette.

Container labeled "[REDACTED] - right lung upper lobe" has a previously partially sectioned recognizable portion of pulmonary parenchyma consistent with right upper lobe. The specimen is received after tissue harvest for genomic study. Within the specimen container are two cassettes labeled "[REDACTED]". The specimen weighs 150 grams and measures 14.7 x 9.6 x 2.8 cm. The margin of resection is the stapled tertiary bronchi surrounded by a few gray-black fleshy nodules up to 1.0 cm. The pleura is smooth and tan-pink with moderate anthracotic streaking. Noted on the medial aspect of the apex is a previously sectioned 2.0 x 1.5 x 1.5 cm area of slightly indurated umbilication. This is sectioned beneath this region to reveal a poorly defined consolidated gray-tan plaque-like lesion measuring 1.7 x 1.6 x 0.9 cm. This has a slightly chalky-appearing tan-gray to pink cut surface. This is noted at its nearest point 4.8 cm from the bronchial margin. A discrete gross bronchial connection is not identified. The lesion extends grossly to but not through the pleura. Sectioning the remaining parenchyma

[REDACTED]

[page 2 of 3]
reveals it to be spongy tan-pink with focal anthracotic streaking. No additional gross lesions are identified. Representative sections are submitted labeled as follows: A - shaved bronchial margin and peribronchial nodules; B-E - remaining lesion and surrounding tissue; F - random uninvolved parenchyma.

Container labeled "[REDACTED] level 9 lymph node" has a 1.0 x 0.7 x 0.6 cm nodular portion of gray-pink to brown-black tissue which is bisected and entirely submitted in a single cassette.

Container labeled "[REDACTED] level 11 lymph node" has a 1.7 x 0.8 x 0.4 cm shaggy lobulated portion of gray-pink to brown-black tissue with focal staples in place. The specimen is entirely submitted in a single cassette.

[REDACTED]
Microscopic Description:
Reviewed are slides labeled [REDACTED]

Final Diagnosis

Lymph node, level 10:

Multiple fragments of benign lymph node with focal calcification; no carcinoma identified in sections examined.

Lung, right upper lobe, lobectomy:

Tumor characteristics:

Specimen integrity: Intact.

Specimen laterality: Right upper lobe.

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated.

Tumor site: Medial aspect of apex, right upper lobe.

Tumor focality: Unifocal.

Tumor size: 2.0 x 1.5 x 1.5 cm.

Visceral pleural invasion: Not identified (see comment).

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified in sections examined.

Tumor extension: Tumor confined to lung parenchyma.

Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: 4.8 cm.

Tumor distance from pleural surface: Less than 1 mm (see comment).

Lymph node status:

Three peribronchial lymph nodes negative for malignancy (0/3).

See also parts 1, 3 and 4.

Other:

Emphysematous change.

pTN stage: pT1a N0

Lymph node, level 9:

One benign lymph node negative for metastatic carcinoma (0/1).

Lymph node, level 11:

One benign lymph node negative for metastatic carcinoma (0/1).

Calcified granulomata.

No acid fast or fungal organisms identified by AFB or GMS stains (with working controls).

[REDACTED]

[REDACTED]

[REDACTED]

[page 3 of 3]
Comments

Histologic sections demonstrate a well to moderately differentiated adenocarcinoma that in areas demonstrates features of bronchoalveolar carcinoma. However, evidence of desmoplastic fibrosis and invasion of this stroma suggests this is better classified as an adenocarcinoma, not otherwise specified. The lesion extends close to, and in many areas abuts, the elastic layer of the visceral pleura; however, definitive extension into this elastic layer is not identified on H and E stained slides. Clinical correlation is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This test has been finalized at the [REDACTED] Campus.

[REDACTED]

Source: NCI Genomic Data Commons file 37987686-0843-4c32-9ebb-24cd294f6df7 (TCGA-55-8097.3E2989F4-213D-4F64-BE03-9B967F1FCC08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).